Gene-level copy-number profile of tumor specimen TCGA-D8-A1JA-01A from TCGA case TCGA-D8-A1JA, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 60.0 years (21,918 days).
Specimen TCGA-D8-A1JA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.05cd681e-6864-4296-88d3-f3848bdaaf58.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A1JA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/37f13b4a-151d-43ad-a948-1515b4cbf8fe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 9,856; copy number 2: 44,708; copy number 3: 4,400; copy number 4: 461; copy number 5: 1; copy number 6: 17; copy number 7: 17; copy number 8: 36; copy number 9: 17; copy number 10: 4; copy number 12: 1; copy number 13: 170; copy number 14: 6; copy number 16: 73; copy number 18: 18; copy number 19: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A1JA-01A-11D-A13J-01): tumor purity 0.77, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 388 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:16,203,935–17,114,122, 7 genes, copy number 6–14 (within-gene range 1–14): C9orf92, BNC2, AL449983.1, AL450003.1, BNC2-AS1, LSM1P1, AL162725.2.
- chr9:17,053,901–18,910,950, 9 genes, copy number 6 (within-gene range 1–6): RN7SL720P, RPS29P33, AL162725.1, CNTLN, SAMM50P1, SH3GL2, PABPC1P11, ADAMTSL1, AL442638.1.
- chr9:19,108,375–23,438,700, 90 genes, copy number 9–16 (within-gene range 4–16) (broad region; genes not listed).
- chr9:24,542,952–27,230,174, 22 genes, copy number 5–12 (within-gene range 1–12): IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK.
- chr9:27,937,617–27,944,497, 1 gene, copy number 9: AL353746.1.
- chr17:39,461,486–39,877,896, 18 genes, copy number 18 (within-gene range 1–18): CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2.
- chr17:47,733,236–52,160,017, 198 genes, copy number 10–19 (within-gene range 2–19) (broad region; genes not listed).
- chr17:61,354,763–61,413,280, 6 genes, copy number 6: AC005746.3, AC005746.2, AC005746.1, TBX2-AS1, TBX2, LINC02875.
- chr17:61,460,224–61,463,384, 1 gene, copy number 6: AC005901.1.
- chr17:75,205,659–75,575,209, 19 genes, copy number 8 (within-gene range 3–8): NUP85, GGA3, MRPS7, MIF4GD, AC022211.2, SLC25A19, GRB2, AC011933.1, AC011933.4, AC011933.2, AC011933.3, MIR3678, RNU6-938P, Y_RNA, TMEM94, MIR6785, CASKIN2, TSEN54, LLGL2.
- chr17:76,389,456–76,595,772, 17 genes, copy number 7 (within-gene range 3–7): UBE2O, RPL7P49, AANAT, RHBDF2, CYGB, PRCD, AC015802.4, AC015802.3, AC015802.5, SNHG16, SNORD1C, SNORD1B, SNORD1A, AC015802.6, ST6GALNAC2, AC015802.1, AC015802.2.

Autosomal genes at a single copy (total copy number 1): 9,856. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
